Gene-level copy-number profile of tumor specimen TCGA-3M-AB46-01A from TCGA case TCGA-3M-AB46, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lesser curvature of stomach, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2.
Specimen TCGA-3M-AB46-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.1e469e9c-15cc-4dee-9905-465d86826f62.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3M-AB46-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/00b311b4-2937-4779-9ab4-61c4e5321bdc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 17,340; copy number 2: 27,709; copy number 3: 13,484; copy number 4: 1,147; copy number 8: 131.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3M-AB46-01A-11D-A40Z-01): tumor purity 0.74, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:74,627,406–74,641,424, 1 gene: ENC1.
- chr18:50,967,991–51,085,045, 3 genes: ELAC1, AC091551.1, SMAD4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 131 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:33,817,160–36,677,683, 131 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15,161. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
